Surgical pathology report (de-identified scan), TCGA case TCGA-24-1852, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Washington University, specimen TCGA-24-1852-01A (Primary Tumor).

[page 1 of 5]
ICD-0-3
carcinoma, serous, papillary 8461/3
Site: ovary, nos. C56.9

hw
1/26/15

Name:
Address:

MR No.:
Service:
Surgeon:

M.D.

Surg. Path. No.:
DOB:
Sex/Race:
Location:
Hosp. No.:
Taken/Received:

DIAGNOSIS

OVARIES , LEFT AND RIGHT, BILATERAL SALPINGO-OOPHORECTOMY
- PAPILLARY SEROUS CARCINOMA
- SEE SYNOPTIC

FALLOPIAN TUBES, RIGHT AND LEFT, BILATERAL SALPINGO-OOPHORECTOMY
- CYSTIC WALTHARD'S NESTS

UTERUS, CERVIX, TOTAL ABDOMINAL HYSTERECTOMY
- SQUAMOUS METAPLASIA
- FOCAL SUBSEROSAL ENDOMETRIOSIS

UTERUS, ENDOMETRIUM, TOTAL ABDOMINAL HYSTERECTOMY - WEAKLY
PROLIFERATIVE

UTERUS, MYOMETRIUM, TOTAL ABDOMINAL HYSTERECTOMY - FOCAL
ADENOMYOSIS

SOFT TISSUE, RIGHT PELVIC, BIOPSY - METASTATIC PAPILLARY SEROUS
CARCINOMA

SOFT TISSUE, LEFT PELVIS, BIOPSY - NO EVIDENCE OF MALIGNANCY

SOFT TISSUE, ANTERIOR CULDE-SAC, BIOPSY - NO EVIDENCE OF
MALIGNANCY

SOFT TISSUE, POSTERIOR CULDE-SAC, BIOPSY - NO EVIDENCE OF
MALIGNANCY

SOFT TISSUE, RIGHT GUTTER, BIOPSY - NO EVIDENCE OF MALIGNANCY

SOFT TISSUE, LEFT GUTTER, BIOPSY - NO EVIDENCE OF MALIGNANCY

LYMPH NODES, RIGHT EXTERNAL ILIAC, EXCISION - NO EVIDENCE OF
MALIGNANCY IN TWO LYMPH NODES

LYMPH NODES, LEFT EXTERNAL ILIAC, EXCISION - NO EVIDENCE OF
MALIGNANCY IN THREE LYMPH NODES

LYMPH NODES, RIGHT OBTURATOR, EXCISION - NO EVIDENCE OF MALIGNANCY
IN THREE LYMPH NODES

LYMPH NODES, LEFT OBTURATOR, EXCISION - NO EVIDENCE OF MALIGNANCY
IN FOUR LYMPH NODES

[page 2 of 5]
Name:

Surg. Path. No.:

DIAGNOSIS (continued)

LYMPH NODE, RIGHT COMMON PERIAORTIC, EXCISION - NO EVIDENCE OF
MALIGNANCY IN ONE LYMPH NODE

LYMPH NODE, LEFT PERIAORTIC, EXCISION - NO EVIDENCE OF MALIGNANCY
IN ONE LYMPH NODE

OMENTUM, EXCISION - MULTIPLE MICROSCOPIC FOCI OF METASTATIC
PAPILLARY SEROUS CARCINOMA

By this signature, I attest that the
above diagnosis is based upon my
personal examination of the slides
(and/or other material indicated in
the diagnosis), and, that I have
reviewed and approved this report.

SPECIMEN(S) SUBMITTED

- Part 1: RIGHT OVARY
- Part 2: TAH AND LSO
- Part 3: POSTERIOR CUL DE SAC
- Part 4: ANTERIOR CUL DE SAC
- Part 5: RIGHT PELVIS
- Part 6: LEFT PELVIS
- Part 7: LEFT GUTTER
- Part 8: RIGHT GUTTER
- Part 9: LEFT EXTERNAL ILIAC LYMPH NODES
- Part 10: LEFT OBTURATOR LYMPH NODES
- Part 11: LEFT COMMON PERIAORTIC LYMPH NODES
- Part 12: RIGHT EXTERNAL ILIAC LYMPH NODES
- Part 13: RIGHT OBTURATOR LYMPH NODES
- Part 14: RIGHT COMMON PERIAORTIC LYMPH NODES
- Part 15: OMENTUM

STORY

The patient is a year old woman with an adnexal mass, ascites,
and an elevated CA125. Clinical diagnosis: Rule out malignancy.
Operative procedure: Total abdominal hysterectomy, bilateral
salpingo-oophorectomy and lymph node sampling.

An intraoperative non-microscopic consultation was obtained and

[page 3 of 5]
Surg. Path. No.:

Name:

HISTORY (continued)

interpreted as: "Called to O.R. to pick up a specimen labeled as "right ovary," which consists of a large cystic mass measuring 21.0 x 17.0 x 5.5 cm. Upon sectioning, a large amount of burgundy-red fluid was drained and several solid nodular masses were identified with variegated cut surfaces. The largest mass measures approximately 5.0 cm in greatest dimension."

GROSS

The specimens are received in fifteen containers of formalin, each labelled with the patient's name. The first container is additionally labeled "right ovary." It contains a previously sectioned cystic ovarian mass, which, upon reconstruction, conforms to the above dimensions. The serosal surface of the ovary is smooth and grossly unremarkable. The attached fallopian tube measures 4.5 cm in length (including the fimbriated end) and 0.8 cm in greatest diameter. The serosal surface of the fallopian tube is slightly nodular, but not suspicious for tumor. On cross section, an unremarkable lumen is identified. The internal surface of the multicystic ovary is notable for numerous broad-based nodular surfaces. In one portion of the ovary which measures approximately 11.0 cm in greatest diameter, a solid mass is noted in some areas, the mass is firm, white and trabeculated, suggestive of smooth muscle. In other areas it is tan-white, nodular, focally necrotic and degenerating. No definitive papillary excrescences are identified on gross examination. Labeled A1 - fallopian tube; A2 through A12 - sections of ovarian mass (two independent sections per cassette). Jar 3.

The second container is additionally labeled "TAH-BSO." It contains a hysterectomy specimen with attached left adnexa. The uterus measures 8.5 x 5.5 x 4.0 cm, weighs 132 gms. and has a smooth unremarkable serosal surface. The cervix measures 2.8 cm in length and 3.5 cm in greatest diameter. It contains a slit-like os measuring 0.6 cm in length. The left fallopian tube is 5.5 cm in length, 0.5 cm in greatest diameter. It is extremely remarkable for a 2.5 cm cystic dilatation which, on cross section contains clear fluid. The internal external linings of the cyst are grossly unremarkable. On cross section, an unremarkable lumen is identified. The attached left ovary measures 3.0 x 2.5 x 1.5 cm and is focally cystic. In addition, there is an area on the surface of the ovary measuring 1.5 cm in greatest dimension which is tan, papillary in nature and grossly suspicious for tumor. The cystic structure, which measures 1.5 cm in greatest diameter has a smooth internal lining, is grossly unremarkable. No additional lesions are identified grossly on external examination. The uterus is bivalved in the coronal plane to show an unremarkable endocervical canal which measures 2.5 cm in length and 0.5 cm in

[page 4 of 5]
Surg. Path. No.:

Name:

GROSS (continued)

greatest diameter. No gross lesions are identified. The endometrial cavity measures 2.3 x 4.0 cm and has a thin, slightly hemorrhagic endometrial lining measuring approximately 0.05 cm in thickness. No focal lesions are identified. Serial sections through the myometrium show no focal lesions. Labeled B1 - left fallopian tube; B2 and B3 - left ovary with tumor and cystic area; B4 - anterior cervix; B5 - posterior cervix; B6 - anterior endomyometrium; B7 - posterior endomyometrium. Jar 2.

The third container is additionally labeled "posterior cul-de-sac biopsy." It contains a single irregularly shaped fragment of tan-white tissue measuring 0.8 x 0.3 x 0.2 cm. Labeled C. Jar 0.

The fourth container is additionally labeled "right pelvic biopsy." It contains two irregularly shaped fragments of tan-white mucosal tissue ranging from 0.5 to 0.9 cm in greatest dimension. Labeled D. Jar 0.

The fifth container is additionally labeled "anterior cul-de-sac biopsy." It contains a single irregularly shaped fragment of tan-grey, soft, tissue measuring 0.5 x 0.4 x 0.2 cm in greatest dimension. Labeled E. Jar 0.

The sixth container is additionally labeled "left pelvic biopsy." It contains a single irregularly shaped fragment of tan and brown mucosal tissue measuring 0.9 x 0.6 x 0.2 cm in greatest dimension. Labeled F. Jar 0.

The seventh container is additionally labeled "left gutter biopsy." It contains two irregularly shaped fragments of yellow, lobulated adipose tissue measuring 0.8 x 0.4 x 0.2 cm in greatest dimension each. Labeled G. Jar 0.

The eighth container is additionally labeled "right gutter biopsy." It contains a single membranous fragment of tan-white soft tissue measuring 0.5 x 0.4 x < 0.1 cm in greatest dimension. Labeled H. Jar 0.

The ninth container is additionally labeled "right obturator biopsy." It contains a single irregularly shaped fragment of yellow lobulated adipose tissue measuring 2.9 x 1.5 x 0.4 cm. The fragment is dissected to show three possible lymph nodes ranging from 0.3 to 1.2 cm in greatest diameter. Labeled J. Jar 1.

The tenth container is additionally labeled "left obturator biopsy." It contains a single irregularly shaped fragment of yellow, lobulated adipose tissue measuring 5.5 x 2.2 x 1.5 cm in greatest dimension. Three possible lymph nodes ranging from 0.5 to 3.5 cm in greatest dimension. Labeled K1, K2 Jar 1

[page 5 of 5]
Name:

Surg. Path. No.:

COMMENT (continued)

metastases of serous carcinoma are present in the omentum.

There is no evidence of metastatic serous carcinoma in the fourteen lymph nodes from the right external iliac, left external iliac, right obturator, left obturator, right common periaortic, and left periaortic sites.

SYNOPTIC REPORTING FORM FOR MALIGNANT OVARIAN NEOPLASMS

1. A neoplasm is PRESENT.
2. The HISTOLOGIC DIAGNOSIS is:
Papillary serous carcinoma
3. The LOCATION(S) OF THE PRIMARY TUMOR(S) is/are:
Right and left ovary (synchronous primary tumors)
4. The FIGO GRADE of the tumor is:
Not applicable.
5. The NUCLEAR (BRODERS') GRADE of the tumor is:
G3 (Poorly-differentiated)
6. Tumor IS identified on the left and right ovarian surface(s).
7. Tumor DOES NOT invade the mesovarium.
8. Tumor DOES NOT invade the adjacent fallopian tubes.
9. Tumor DOES NOT invade the pelvic soft tissue.
10. Tumor involvement of the pelvic peritoneum is PRESENT.
11. Metastatic involvement of the EXTRAPELVIC peritoneum is ABSENT.
12. Metastatic involvement of the omentum is PRESENT.
13. The maximum dimension of tumor implants outside the true pelvis is 0.2 cm. (Enter "0" if no implants.)
14. Metastatic involvement of the uterine serosa is ABSENT.
15. Metastatic involvement of the endometrium is ABSENT.
16. Regional lymph node metastases are ABSENT.
17. The total number of regional lymph nodes examined is 14
18. The total number of metastatically-involved regional lymph nodes is zero.
Extranodal extension by tumor is NOT APPLICABLE; no nodal metastases are present
19. DETAILED STAGING INFORMATION:
Based on the above information, the PRIMARY TUMOR is classified as:

TNM SCHEME	FIGO SCHEME	DEFINITION
T3a	IIIA	Microscopic peritoneal metastasis beyond true pelvis

THE REGIONAL LYMPH NODES are classified as:

N0 (Nodes are free of metastases)

THE STATUS OF DISTANT TUMOR SITES is classified as:

MX (Status cannot be assessed).

Source: NCI Genomic Data Commons file 114fe440-caf0-415f-89d9-473a6c1d2634 (TCGA-24-1852.FC6FD336-EB96-40CD-91FB-9371A305EF76.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).